CCDI case PBCEIZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a6abdb93-5886-445f-b44c-6651b459f927

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Schwannoma, NOS: ICD-O-3 morphology code: 9560/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.1 years (3,701 days).

Biospecimens (3 samples)
- Sample 0DQ7WC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQ7WM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQ80R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
